Surgical pathology report (de-identified scan), TCGA case TCGA-TS-A7P7, project TCGA-MESO (Mesothelioma), tissue source site University of Pennsylvania, specimen TCGA-TS-A7P7-01A (Primary Tumor).

[page 1 of 6]
Age: years Sex: Male

Date Printed:
Date Collected :
Date Received:
Accession N
Physician:
Copy to:

Addendum Report

Addendum Discussion

Specimen #6:

AFB stain for acid fast bacilli is negative.
Grocott stain for fungal organism is negative.

The case material was reviewed and the report verified by:
(Electronic signature)
Verification Date:

Cycr *ICD-O-3*
Mesothelioma, epithelioid
NOS *9052/3*
path
Mesothelioma, biphasic NOS
9053/3
Site: Pleura NOS
9053/3
9/24/13

Surgical Pathology Report

Clinical Information

year old male with no clinical history given; Left Thoracotomy, PDT, Radical Pleurectomy

Final Diagnosis

1. SKIN, PREVIOUS BIOPSY SITE:

Skin with dermal fibrosis, chronic inflammation and foreign body giant cell reaction consistent with previous biopsy site.
No evidence of residual tumor.

2. RIB:

Benign cancellous bone containing scant unremarkable bone marrow elements.
Adherent benign striated muscle and fibroadipose tissue.

3. POSTERIOR INTERCOSTAL NODE:

Two of three lymph nodes positive for metastatic biphasic malignant neoplasm.
Supported by calretinin and D2-40 immunostains.

4. BASILAR LUNG NODULE:

Benign lung parenchyma with organizing fibrosis, chronic inflammation, reactive type II pneumocytes hyperplasia and scattered foci of non-necrotizing granulomas.
Supported by TTF-1, CK5/6 and calretinin immunostains.

Name:
MRN:

Page 1 of 5

[page 2 of 6]
Name: [REDACTED]
MRN: [REDACTED]
Age: [REDACTED] years Sex: Male

Date Printed: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Accession No: [REDACTED]
Physician: [REDACTED]
Copy to: [REDACTED]

S u r g i c a l P a t h o l o g y R e p o r t

Negative for malignancy.

5. LEVEL 5 NODE:

Fragments of lymph node showing foci of ill-defined and well-defined non-necrotizing granulomas.
No tumor seen.

6. LEVEL 8 NODE:

Fragments of lymph node showing foci of well-defined and ill-defined non-necrotizing granulomas.
No tumor seen.
AFB stain for acid fast bacilli and Grocott stain for fungal organism are pending.

7. LEVEL 9 NODE:

Fragments of lymph node showing foci of well-defined and ill-defined non-necrotizing granulomas.
No tumor seen.

8. POSTERIOR HILAR NODE:

Fragments of lymph node showing foci of well-defined and ill-defined non-necrotizing granulomas.
No tumor seen.

9. LEVEL 6:

A fragment of benign mature adipose tissue containing scattered lymphoid aggregate.
No lymph nodes identified grossly.

10. LEVEL 7:

Fragments of lymph node showing foci of well-defined and ill-defined non-necrotizing granuloma.
No tumor seen.

11. RADICAL PLEURECTOMY:

Poorly differentiated biphasic malignant neoplasm most consistent with sarcomatoid mesothelioma.
Tumor does not invade the adherent lung parenchyma.

12. PERICARDIUM:

Poorly differentiated biphasic malignant neoplasm most consistent with sarcomatoid mesothelioma.

13. POSTERIOR INTERCOSTAL NODE:

Name: [REDACTED]
MRN: [REDACTED]

[page 3 of 6]
Name: [REDACTED]
MRN: [REDACTED]
Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected :
Date Received:
Accession No: [REDACTED]
Physician: [REDACTED]
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

One lymph node, no tumor seen.

The case material was reviewed and the report verified by:
(Electronic signature)
Verification Date

Note

Immunostain with adequate controls performed on block 11F reveal epithelioid tumor cells are positive for AE1-3, Pan-keratin, Calretinin, D2-40 and Mic-2. Spindle cell component of tumor cells are positive for SMA and Mic-2. Both spindle cells and epithelioid cells are negative for Bcl-2, Desmin, HMB45, S100, CD34, CEA, WT-1, TTF-1, BRST-2 and CK7. Tumor cells appear to be aberrantly express TLE and myogenin. Combined morphological and immunological features are consistent sarcomatoid mesothelioma.

Slides from specimen #11 reviewed by

Frozen Section Diagnosis

FS1A,B,C: Entire section from previous biopsy scar area shows fibrosis and chronic inflammation.
No tumor seen.

Gross Description

The case is received in 13 containers, each labeled with the patient's name and medical record number.

Specimen #1 is received fresh for frozen section, designated as "Skin Previous Biopsy Site" and consists of a 5.5 x 1.0 cm skin ellipse excised to a depth of 2.0 cm. The deep surface is inked black at the time of frozen section. There is an ill-defined scar on the skin surface; this area is submitted entirely for frozen section as FS1A through FS1C. The frozen section controls are submitted in cassettes 1A through 1C, respectively an additional representative sections of the remainder of the specimen are submitted in cassette 1D.

Specimen #2 is received in formalin, designated as "Rib" and consists of a 2.8 x 1.4 x 0.5 cm ragged an irregular fragment of tan-white, firm bone which has a small amount of attached adipose tissue. The specimen is serially sectioned and submitted entirely in cassette 2A following decalcification.

Specimen #3 is received in formalin, designated as "Posterior Intercostal Node" and consists of four tan-yellow, irregular soft tissue fragments ranging from 0.5 to 0.8 cm in greatest dimension. The specimen is submitted in toto in cassette 3A.

Name: [REDACTED]
MRN: [REDACTED]

[page 4 of 6]
Name: [REDACTED]
MRN: [REDACTED]
Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed: [REDACTED]
Date Collected: [REDACTED]
Date Received: [REDACTED]
Accession No.: [REDACTED]
Physician: [REDACTED]
Copy to: [REDACTED]

S u r g i c a l P a t h o l o g y R e p o r t

Specimen #4 is received in formalin, designated as "Basilar Lung Nodule" and consists of five tan-gray, irregular soft tissue fragments measuring 0.4, 0.4, 0.5, 0.6 and 0.9 cm in greatest dimension. The specimen is submitted in toto in cassette 4A.

Specimen #5 is received in formalin, designated as "Level 5 Node" and consists of a 2.2 x 1.3 x 0.5 cm irregular fragment of tan-yellow, rubbery adipose tissue, which is bisected to reveal a gray-black, possible lymph node measuring 1.1 cm in greatest dimension. The specimen is submitted entirely in cassette 5A.

Specimen #6 is received in formalin, designated as "Level 8 Node" and consists of a 1.4 x 1.1 x 0.7 cm tan-gray, rubbery, possible lymph node, which is bisected to reveal tan-gray, dense cut surfaces. The specimen is submitted entirely in cassette 6A.

Specimen #7 is received in formalin, designated as "Level 9 Node" and consists of a 2.2 x 1.5 x 0.8 cm tan-yellow to gray-black, irregular soft tissue fragment, which is bisected to reveal tan-white to gray-black, dense cut surfaces. The specimen is submitted entirely in cassette 7A.

Specimen #8 is received in formalin, designated as "Posterior Hilar Node" and consists of multiple grey black, friable soft tissue fragments measuring 1.5 x 0.8 x 0.3 cm in aggregate. The specimen is submitted in toto in cassette 8A.

Specimen #9 is received in formalin, designated as "Level 6" and consists of a 0.7 x 0.6 x 0.3 cm tan-yellow, irregular soft tissue fragment, which is submitted in toto in cassette 9A.

Specimen #10 is received in formalin, designated as "Level 7" and consists of two gray-black, irregular soft tissue fragments measuring 0.5 and 1.3 cm in greatest dimension. The largest fragment is bisected and the specimen is submitted entirely in cassette 10A.

Specimen #11 is received in formalin, designated as "Radical Pleurectomy" and consists of an unoriented portion of tan-gray to tan-yellow, lobulated soft tissue, grossly consistent with a portion of pleura. There is a 15.5 x 12.0 cm portion which displays a red-brown, rubbery muscle and tan-white fibrous tissue, grossly consistent with a portion of the diaphragm (inked black). The remainder of the specimen cannot be oriented grossly. Sectioning reveals multiple tan-white, whorled, dense nodules and thickened areas measuring up to 12.5 cm in greatest dimension. The remaining cut surfaces are comprised of tan-yellow, lobulated adipose tissue. Representative sections are submitted in cassettes 11A through 11F.

Specimen #12 is received in formalin, designated as "Pericardium" and consists of a 7.2 x 4.3 x 0.6 cm ragged an irregular fragment of gray purple, glistening soft tissue. There is an ill-defined 1.8 x 1.3 x 0.8 cm tan-white, firm nodule which is sectioned to reveal tan-white, dense cut surfaces. The nodule is submitted in its entirety in cassette 12A and additional representative sections are submitted in cassette 12B.

Specimen #13 is received in formalin, designated as "Posterior Intercostal Node" and consists of a 1.4 x 1.0 x 0.4 cm tan-yellow, regular fragment of soft tissue, which is bisected to reveal tan-yellow, glistening cut surfaces. The specimen is

Name: [REDACTED]
MRN: [REDACTED]

[page 5 of 6]
Name: [REDACTED]
MRN: [REDACTED]
Age: [REDACTED] years Sex: Male
Loc.: [REDACTED]

Date Printed:
Date Collected
Date Received:
Accession No: [REDACTED]
Physician:
Copy to:

S u r g i c a l P a t h o l o g y R e p o r t

submitted entirely in cassette 13A.

Dictated by:

Pathologist(s)

Name: [REDACTED]
MRN: [REDACTED]

*Per TSS Dx discrepancy form,
TCGA specimen is epithelioid,
not biphasic. OK* Page 5 of 5

[page 6 of 6]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Mesothelioma -	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

biphasic Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

epithelioid Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

Submitted specimen is epithelioid while the clinical frozen specimen reviewed for diagnosis showed sarcomatoid as well; Pathology report indicates diagnosis of biphasic.

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file 56a07c4f-ff8a-452a-b4bb-b4d8c57de1fd (TCGA-TS-A7P7.809D0A50-C963-491E-87B7-A15E4BF2FC07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).